CCDI case PBBZVU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e26f40e1-666f-43e9-ad6c-22227175fb40

Demographics
Sex at birth: female; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.3 years (4,128 days).

Biospecimens (3 samples)
- Sample 0DLZND: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLZOK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DLZOP: Tissue type: Tumor; Specimen type: Solid Tissue.
